CCDI case PBBSUN — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Granular Cell Tumors and Alveolar Soft Part Sarcomas; Primary site: Bones, joints and articular cartilage of limbs.
https://portal.gdc.cancer.gov/cases/78093b0d-5f34-467b-b1d7-ba708bf89a9d

Demographics
Sex at birth: female; Race: black or african american; Vital status: Alive.

Diagnoses (1)
1. Alveolar rhabdomyosarcoma: ICD-O-3 morphology code: 8920/3; Tissue or organ of origin: Lower limb, NOS; Age at diagnosis: 1.5 years (559 days).

Biospecimens (3 samples)
- Sample 0DGO9Z: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DGOAR: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DGOBF: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
